Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19G, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19G-06A (Metastatic).

ICD-0-3

Melanoma, NOS 8720/3

12/4/10

hr

PATIENT HISTORY:

Site Code: axilla, NOS C44.5

* DATE of LMP: *

DATE OF LAST DELIVERY: *

PRE-OP DIAGNOSIS: METASTATIC MELANOMA R AXILLA

POST-OP DIAGNOSIS: SAME

OPERATIVE PROCEDURE: R AXILLARY DISSECTION

CLINICAL HISTORY: *

MATERIAL SUBMITTED: RIGHT AXILLA, PROCUREMENT BY SURGICAL PROCEDURE

FINAL DIAGNOSIS:

FINAL DIAGNOSIS:

RIGHT AXILLARY CONTENTS:

- THREE (3) LYMPH NODES POSITIVE FOR METASTATIC MALIGNANT MELANOMA

NOTE: The lymph nodes are completely replaced by metastatic tumor and one appears to show extracapsular extension. The positive status of the lymph nodes is confirmed by the S100 and HMB-45 immunostains.

The special stains and/or immunoperoxidase tests used in this case have been developed and their performance characteristics determined by the Department of Pathology at

They have not been cleared or approved by the U.S. Food and Drug Administration.

Source: NCI Genomic Data Commons file 9dd101d7-cb30-4bb3-9479-7393b9a7381a (TCGA-ER-A19G.4F69932E-54F7-487B-A7D2-7787F9544AE8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).